Gene-level copy-number profile of tumor specimen TCGA-24-2281-01A from TCGA case TCGA-24-2281, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 68.5 years (25,019 days).
Specimen TCGA-24-2281-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.89a06d96-e657-4d09-89c4-3e0a679ba9ac.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-2281-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/30c19809-60d7-4001-813a-481b82eb44c6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 581; copy number 2: 6,495; copy number 3: 29,246; copy number 4: 17,094; copy number 5: 2,761; copy number 6: 2,036; copy number 7: 921; copy number 8: 159; copy number 9: 82; copy number 10: 10; copy number 11: 55; copy number 12: 20; copy number 13: 57; copy number 14: 38; copy number 15: 20; copy number 17: 5; copy number 18: 21; copy number 19: 58; copy number 21: 30; copy number 24: 5; copy number 26: 20; copy number 29: 37; copy number 31: 30; copy number 39: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-2281-01A-01D-0704-01): tumor purity 0.5, ploidy 3.4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:11,157,455–12,143,830, 12 genes (within-gene range 0–4): RN7SL601P, AC005548.1, SHISA6, AC005725.1, DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744.
- chr17:21,428,263–21,641,536, 13 genes: LINC02693, AC068418.3, PDLIM1P2, AC068418.2, AC068418.1, RPL21P120, AC233702.5, AC233702.7, AC233702.8, AC233702.6, AC233702.3, AC233702.2, AC233702.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,573 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,383,838–41,242,154, 95 genes, copy number 7–11 (within-gene range 6–11) (broad region; genes not listed).
- chr2:113,829,390–114,123,293, 10 genes, copy number 10: AC104653.2, AC104653.1, AC110769.2, ACTR3, AC110769.3, LINC01191, AC110769.1, U3, AC010982.2, AC010982.1.
- chr2:119,156,243–122,887,691, 53 genes, copy number 8–12: C1QL2, RN7SL468P, STEAP3, STEAP3-AS1, C2orf76, DBI, TMEM37, SCTR, SCTR-AS1, CFAP221, TMEM177, RPL17P15, PTPN4, RPL27P7, EPB41L5, AC012363.1, Y_RNA, MTATP6P26, MTCO3P43, MTND3P10, MTND4LP14, MTND4P26, MTND5P28, TMEM185B, RALB, AC012363.2, INHBB, LINC01101, AC073257.2, AC073257.1, Y_RNA, AC018866.1, GLI2, AC017033.1, Y_RNA, AC067960.1, AC079988.1, TFCP2L1, RPS17P7, CLASP1, AC012447.1, RNU4ATAC, Y_RNA, NIFK-AS1, RPL12P15, AC018737.2, NPM1P32, NIFK, TSN, AC018737.1, LINC01823, AC011246.1, AC073632.1.
- chr2:157,736,444–157,876,330, 1 gene, copy number 19 (within-gene range 3–19): ACVR1.
- chr2:157,877,683–157,878,565, 1 gene, copy number 19: AC013731.1.
- chr2:163,593,396–163,736,012, 1 gene, copy number 7 (within-gene range 3–7): FIGN.
- chr2:170,077,224–173,965,702, 64 genes, copy number 11–29 (within-gene range 4–29) (broad region; genes not listed).
- chr2:177,623,244–178,108,339, 2 genes, copy number 8 (within-gene range 6–8): PDE11A, PDE11A.
- chr2:177,953,111–178,462,102, 13 genes, copy number 8: AC011998.2, API5P2, SDHDP5, RNU6-629P, CYCTP, AC011998.1, RBM45, RNU5E-9P, OSBPL6, CHROMR, PRKRA, PJVK, NUDCP2.
- chr2:179,399,728–180,916,939, 12 genes, copy number 7 (within-gene range 5–7): RAD52P1, ZNF385B, TXNL4AP1, MIR1258, AC096587.2, AC096587.1, CWC22, AC012669.1, AC009478.1, SCHLAP1, AC104820.1, FTH1P20.
- chr2:186,032,884–193,277,614, 93 genes, copy number 8–39 (broad region; genes not listed).
- chr3:166,721,458–170,870,208, 75 genes, copy number 7–14 (broad region; genes not listed).
- chr3:192,796,815–195,443,044, 62 genes, copy number 13–17 (within-gene range 3–17) (broad region; genes not listed).
- chr6:23,337,711–25,042,170, 27 genes, copy number 7 (within-gene range 6–7): AL139231.1, AL133270.1, AL139093.1, SPTLC1P2, AL032822.1, HNRNPA1P58, NRSN1, FO393410.1, DCDC2, KAAG1, RNU6-391P, MRS2, GPLD1, ALDH5A1, KIAA0319, KRT8P43, TDP2, ACOT13, AL031775.1, C6orf62, AL031775.2, LINC02828, AL133264.1, GMNN, ARMH2, AL512428.1, RIPOR2.
- chr6:33,572,547–34,000,051, 14 genes, copy number 7 (within-gene range 5–7): BAK1, LINC00336, ITPR3, UQCC2, MIR3934, IP6K3, LEMD2, MLN, AL138889.3, LINC01016, AL138889.2, AL138889.1, MIR7159, MIR1275.
- chr8:109,298,598–145,066,685, 547 genes, copy number 7 (broad region; genes not listed).
- chr11:76,591,023–95,012,532, 350 genes, copy number 7–26 (broad region; genes not listed).
- chr11:118,436,490–118,679,690, 12 genes, copy number 15 (within-gene range 3–15): KMT2A, AP001267.3, TTC36, TMEM25, IFT46, RPL5P30, ARCN1, RNU6-1157P, PHLDB1, AP000941.1, MIR6716, TREH.
- chr18:25,818,234–27,190,698, 22 genes, copy number 12–18 (within-gene range 5–21): RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3.
- chr18:26,906,481–27,185,308, 1 gene, copy number 21 (within-gene range 5–21): CHST9.
- chr18:27,225,742–27,247,188, 1 gene, copy number 21: LINC01908.
- chr18:32,091,874–38,688,033, 83 genes, copy number 8–9 (within-gene range 6–9) (broad region; genes not listed).
- chr18:39,622,123–40,247,367, 11 genes, copy number 14–19: MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P, LINC01901, LINC01902, AC011266.1, LINC01477, RPL17P45, AC068688.1.
- chr18:79,069,285–79,378,287, 1 gene, copy number 7 (within-gene range 3–7): ATP9B.
- chr18:79,185,801–79,951,657, 22 genes, copy number 7–29: AC125437.3, AC104423.1, AC023090.1, AC023090.2, NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2, AC018445.6, AC068473.3, AC068473.4, AC068473.1, AC068473.5, CTDP1, AC068473.2, AC021594.1, AC021594.2, KCNG2, AC114341.1, SLC66A2.

Autosomal genes at a single copy (total copy number 1): 581. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
